Somatic mutation profile of tumor specimen TCGA-CD-8525-01A (aliquot TCGA-CD-8525-01A-11D-2340-08) from TCGA case TCGA-CD-8525, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 82.1 years (30,004 days).
Specimen TCGA-CD-8525-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c9ee1ef-576f-4453-8590-6ee24f68fa74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-8525-10A (Blood Derived Normal), aliquot TCGA-CD-8525-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46f505c1-983f-48c7-95f4-5add5059029d

The open-access MAF lists 79 somatic variants for this specimen: 61 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 15, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, RNA 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 20/36 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1150181, COSV63971689; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM30 | c.839A>T p.K280I | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65560269; called by muse, mutect2, varscan2
- AFDN | c.3670C>T p.Q1224* | Nonsense Mutation (SNP) | VAF 4/76 reads (5%) | catalogued as COSV100652662; called by muse, mutect2
- ANK1 | c.3896G>A p.G1299E | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55872156, COSV99226279; called by muse, mutect2
- ASB7 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58403252; called by muse, mutect2, varscan2
- AWAT1 | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV65738130; called by muse, mutect2, varscan2
- BRD8 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as COSV50145104; called by muse, mutect2, varscan2
- BTN3A3 | c.1499G>T p.R500I | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV55070799; called by muse, mutect2, varscan2
- CCDC71 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV58909711, COSV58909842; called by muse, mutect2, varscan2
- CDON | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54994896; called by muse, mutect2, varscan2
- CNDP2 | c.222G>C p.E74D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV60838938; called by muse, mutect2, varscan2
- COL10A1 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV54571914; called by muse, mutect2, varscan2
- CRTC1 | c.886+1G>A p.X296_splice | Splice Site (SNP) | VAF 4/13 reads (31%) | catalogued as COSV58716274; called by muse, varscan2
- DGKD | c.1439A>G p.Y480C (on ENST00000264057 / NM_152879.3; = p.Y436C on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs773496335, COSV51032904; called by muse, mutect2, varscan2
- DRP2 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.011); catalogued as COSV65809162; called by muse, mutect2, varscan2
- FAM71C | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.715); catalogued as COSV60942550; called by muse, mutect2, varscan2
- FOXF1 | c.470T>C p.M157T | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV52284858; called by muse, mutect2, varscan2
- GPATCH3 | c.817T>C p.C273R | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV64651541; called by muse, mutect2, varscan2
- GPR37 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV58255245; called by muse, mutect2, varscan2
- GPR50 | c.1543C>A p.P515T | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV54436707; called by muse, mutect2, varscan2
- GRM8 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs769457476, COSV58799993; called by muse, mutect2, varscan2
- IQUB | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760765844, COSV61236665; called by muse, mutect2, varscan2
- KCNQ5 | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59648592, COSV59659658; called by muse, mutect2, varscan2
- MAMDC2 | c.1633G>C p.D545H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65852226; called by muse, mutect2, varscan2
- MARF1 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.761); catalogued as rs779061671, COSV60019657; called by muse, mutect2, varscan2
- MMP20 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52773750; called by muse, mutect2, varscan2
- NUP160 | c.3271C>T p.R1091C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs551317169, COSV65853422; called by muse, mutect2, varscan2
- OR2L8 | c.346T>G p.S116A | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV61725514; called by muse, mutect2, varscan2
- OR2M4 | c.123A>C p.E41D | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV60707142; called by muse, mutect2, varscan2
- OS9 | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs373204693, COSV57726990; called by muse, mutect2, varscan2
- OTUD7A | c.1546C>T p.R516C (on ENST00000307050 / NM_001382637.1; = p.R509C on NM_130901.3) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747699554, COSV61035874; called by muse, mutect2
- PCDHAC1 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs781843995, COSV53836291; called by muse, mutect2, varscan2
- PCDHB11 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV61309769, COSV61309990; called by muse, mutect2
- PHYHIP | c.138T>G p.N46K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.576); catalogued as COSV58687960; called by muse, mutect2, varscan2
- PIK3CB | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.523); catalogued as rs1217537873, COSV56683158; called by muse, mutect2, varscan2
- PTPRK | c.2086T>G p.F696V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV63890865; called by muse, mutect2, varscan2
- RABEP2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs751883197, COSV62868383; called by muse, mutect2, varscan2
- RANBP3L | c.1377_1380del p.R459Sfs*12 | Frame Shift Del (DEL) | VAF 34/146 reads (23%) | catalogued as rs754638549; called by pindel, varscan2
- RC3H1 | c.1982A>G p.Q661R | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV51197789; called by muse, mutect2, varscan2
- RNF146 | c.485G>A p.R162H (on ENST00000368314 / NM_001242850.2; = p.R161H on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420065912, COSV58931295; called by muse, mutect2, varscan2
- RP1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs374931762, COSV55109638; called by muse, mutect2, varscan2
- SLC16A9 | c.197-1G>T p.X66_splice | Splice Site (SNP) | VAF 26/99 reads (26%) | catalogued as COSV68098190; called by muse, mutect2, varscan2
- SLC6A14 | c.526A>G p.S176G | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV64146042; called by muse, mutect2, varscan2
- SNW1 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs781514092, COSV55052986; called by muse, mutect2, varscan2
- SOHLH2 | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV58520659; called by muse, mutect2, varscan2
- SPTY2D1 | c.314C>G p.S105* | Nonsense Mutation (SNP) | VAF 16/138 reads (12%) | catalogued as COSV60472777; called by muse, mutect2, varscan2
- SUMO4 | c.266A>C p.Q89P | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV53850881, COSV53852479; called by muse, mutect2
- TENM1 | c.4687G>A p.D1563N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV64424608; called by muse, mutect2, varscan2
- TMEM64 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 19/124 reads (15%) | catalogued as COSV69127561; called by muse, mutect2, varscan2
- TPRX1 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.322); catalogued as rs778459955, COSV59114856; called by muse, mutect2, varscan2
- TTC25 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1555638216, COSV66367497; called by muse, mutect2, varscan2
- TTLL5 | c.3818C>G p.S1273C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as COSV54027564, COSV54032354; called by muse, mutect2, varscan2
- WDR35 | c.3538G>A p.V1180M (on ENST00000345530 / NM_001006657.2; = p.V1169M on NM_020779.4) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV55600341; called by muse, mutect2, varscan2
- XIRP2 | c.6673G>C p.E2225Q (on ENST00000628543; = p.E2400Q on NM_152381.6) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV54681248; called by muse, mutect2, varscan2
- YDJC | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.15); catalogued as rs1333412985, COSV53037109; called by muse, mutect2
- ZNF189 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs757901418, COSV99407128; called by muse, mutect2, varscan2
- ZNF226 | c.767A>G p.E256G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV56195826; called by muse, mutect2, varscan2
- IGHG4 | c.926A>T p.H309L | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INTS6L | c.2527del p.I843* | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | called by mutect2, pindel, varscan2
- PCGF5 | c.481del p.M161* | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- AFDN | c.4680C>T p.L1560= | Silent (SNP) | VAF 4/77 reads (5%) | catalogued as COSV100652672; called by muse, mutect2
- ATP11C | c.2430C>A p.G810= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV59559310; called by muse, mutect2, varscan2
- CPB2 | c.354G>A p.S118= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs191429775, COSV51672180; called by muse, mutect2, varscan2
- HAVCR2 | c.867A>G p.Q289= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV57151691; called by muse, mutect2, varscan2
- HCN1 | c.1518A>G p.G506= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV57492831; called by muse, mutect2
- KRT28 | c.603C>T p.D201= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs200078241, COSV60683493; called by muse, mutect2, varscan2
- LONP1 | c.2134C>T p.L712= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1319163841, COSV61501584; called by muse, mutect2, varscan2
- MED13L | c.4035G>A p.R1345= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV56115500; called by muse, mutect2, varscan2
- PACRGL | c.471T>A p.P157= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV54841326; called by muse, mutect2, varscan2
- PCDH19 | c.648G>A p.P216= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as rs996601558, COSV55257202; ClinVar: likely benign; called by muse, mutect2
- PCDHGA11 | c.2292G>A p.S764= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs758742300, COSV53895279; called by muse, mutect2, varscan2
- SPATA1 | c.348A>G p.V116= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV55361081; called by muse, mutect2, varscan2
- TMEM45A | c.312G>C p.L104= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as rs576842776, COSV60252011; called by muse, mutect2, varscan2
- VPS18 | c.1962C>T p.N654= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV55028751; called by muse, mutect2, varscan2
- WASHC1 | c.738T>C p.V246= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- ACOT9 | c.119-1137A>C | Intron (SNP) | VAF 46/177 reads (26%) | catalogued as COSV100321229; called by muse, mutect2, varscan2
- C14orf177 | n.572A>G | RNA (SNP) | VAF 6/39 reads (15%) | catalogued as rs893793862, COSV57900270; called by muse, mutect2, varscan2
- OSGIN1 | n.1290T>G | RNA (SNP) | VAF 31/122 reads (25%) | catalogued as COSV59419164; called by muse, mutect2, varscan2
